TCGA case TCGA-29-2431 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/996313ef-11e7-459d-ba5f-ac1a4d0de513

Demographics
Sex at birth: female; Race: white; Age at index: 59 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 59.8 years (21,833 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,285 days (3.5 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 390 days (1.1 years); Prescribed dose: 1120; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 138 days; Number of cycles: 6; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 33 days; Days to treatment end: 138 days; Number of cycles: 6; Prescribed dose: 160; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 977 days (2.7 years); Days to treatment end: 1,145 days (3.1 years); Number of cycles: 8; Prescribed dose: 530; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 977 days (2.7 years); Days to treatment end: 1,145 days (3.1 years); Number of cycles: 8; Prescribed dose: 335; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 62.4 years (22,793 days); Days to diagnosis: 960 days (2.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 960 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 960 days (2.6 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,285 days (3.5 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-2431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.5; Intermediate dimension: 0.5; Shortest dimension: 0.3.
  Slide TCGA-29-2431-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-29-2431-01A-01-BS1: Section location: Bottom; Percent tumor cells: 93; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 7.
- Sample TCGA-29-2431-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-29-2431-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,285 days; disease-specific survival: no event (censored), 1,285 days; disease-free interval: event (new tumor event after initially disease-free), 960 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 960 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-2431-01A-01D-1043-01): tumor purity 0.88, ploidy 3.01, whole-genome doublings 1.
